Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2PX, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2PX-01A (Primary Tumor).

[page 1 of 2]
ack
Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type: INPATIENT
Additional Copy to:

Clinical Diagnosis & History:

FNA left lobe _____

Specimens Submitted:

1: Total thyroid

DIAGNOSIS:

1. Total thyroid:

Tumor Type:

Papillary carcinoma, follicular variant

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Left lobe

Tumor Size:

Greatest diameter is 1.2 cm.

Tumor Encapsulation:

Completely surrounded

Capsular Invasion:

Focal invasion

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Not identified

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Exhibits chronic lymphocytic thyroiditis

ICD-0-3

Carcinoma, papillary, follicular variant
8340/3

Site: thyroid, NOS C73.9

hw
8/31/11

[page 2 of 2]
Parathyroid Glands:

Not identified

Lymph Nodes:

Four benign lymph nodes (0/4)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

[REDACTED]

1. The specimen is received fresh labeled "total thyroid" and consists of a thyroid weighing 18.0 g. The right lobe measures 5.5 x 3.0 x 0.9 cm, the left lobe measures 4 x 2 x 1 cm and the isthmus measures 2 x 1.5 x 0.6 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning of the left lobe reveals a 1.2 CM light brown nodule with central cystic degeneration, located at the upper pole of the left lobe and abutting the thyroid capsule. Sections through the right lobe reveal red tan and beefy thyroid parenchyma with a vague nodularity (gelatinous fleshy nodules). The isthmus is red tan and beefy. Representative sections of the specimen (left lobe nodule) are submitted for TPS. The remaining tissue is serially sectioned and representatively submitted.

Summary of sections:

N - nodule, entirely submitted

LL - left lobe

RL - right lobe

IS - isthmus

Summary of Sections:

Part 1: Total thyroid

Block	Sect. Site	PCs
1	IS	1
1	LL	1
2	N	2
2	RL	2

Source: NCI Genomic Data Commons file c04f7fac-57a7-4b33-86c3-0f1999cc715a (TCGA-DJ-A2PX.763C06CF-4DC5-4A5A-B698-224A9E5693A2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).